Somatic mutation profile of tumor specimen 0DV15B from CCDI case PBCMBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.7 years (6,083 days).
Specimen 0DV15B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece33a83-726e-4b6e-8823-50eb78a03874.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/911baec0-b426-4289-b3ef-5b16c76a5884

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Translation Start Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASSF5 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 23/501 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs782455588; called by muse, mutect2
- POMGNT2 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 18/469 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.324); called by muse, mutect2
- ZNF500 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZP4 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 27/776 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2
- ADGRE2 | c.957G>A p.E319= | Silent (SNP) | VAF 60/401 reads (15%) | catalogued as COSV100216504; called by muse, mutect2
- SH3KBP1 | c.1650G>A p.P550= | Silent (SNP) | VAF 36/584 reads (6%) | catalogued as rs199899970, COSV65649527; called by muse, mutect2
- CYP2A13 | c.*32C>T | 3'UTR (SNP) | VAF 81/591 reads (14%) | catalogued as rs760494077, COSV100386567; called by muse, mutect2, varscan2
- TAF7L | c.257-69G>A | Intron (SNP) | VAF 182/369 reads (49%) | called by muse, mutect2, varscan2
